BEATAML1.0 case 2768 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Leukemias, NOS; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/783e0a42-cc67-4716-9cc7-32856a748a38

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Mixed phenotype acute leukemia, B/myeloid, NOS: ICD-O-3 morphology code: 9808/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 29.7 years (10,835 days); Progression or recurrence: no.

Biospecimens (2 samples)
- Sample BA3154D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
- Sample BA3154R: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
